TARGET case TARGET-20-PACEFU — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/508740d8-3e2d-4304-b14b-52076a907f21

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 10 years; Vital status: Dead; Days to death: 659 days (1.8 years).

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 10.2 years (3,714 days); Year of diagnosis: 1998; Days to last follow up: 659 days (1.8 years).
   Treatment given: Protocol identifier: CCG2961.
   Treatment given: Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Recorded as not given: Stem Cell Transplantation, NOS, first complete response.

Follow-up (2 entries)
- Days to follow up: 534 days (1.5 years); Days to first event: 534 days (1.5 years); First event: Relapse.
- Days to follow up: 659 days (1.8 years); Year of follow up: 1999.

Molecular and laboratory tests (laboratory values grouped by visit day)
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Positive.
- NPM1 mutation, nos: Negative.
- NUP98–NSD1 fusion: Positive.
- WT1 mutation, nos: Negative.
- Day 0: Leukocytes 251 ×10³/µL; Blast Count 92%; Bone Marrow blast count 98%.

Biospecimens (1 sample)
- Sample TARGET-20-PACEFU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_LowDepthRNAseq_20230720.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 659
- WBC at Diagnosis: 251
- Bone marrow leukemic blast percentage (%): 98
- Peripheral blasts (%): 92
- CNS disease: No
- Chloroma: No
- FAB Category: M1
- Cytogenetic Complexity: 0
- Primary Cytogenetic Code: Other
- ISCN: I
- FLT3/ITD positive?: Yes
- FLT3/ITD allelic ratio: 0.7
- FLT3 PM: No
- NPM mutation: No
- CEBPA mutation: No
- WT1 mutation: No
- CR status at end of course 1: CR
- CR status at end of course 2: CR
- Risk group: High Risk
- SCT in 1st CR: No
- Bone Marrow Site of Relapse/Induction Failure: Yes
- CNS Site of Relapse/Induction Failure: No
- Chloroma Site of Relapse/Induction Failure: No
- Cytogenetic Site of Relapse/Induction Failure: No
- Other Site of Relapse/Induction Failure: No
- Blast count used for RNA seq: 98
- Gene Fusion: NUP98-NSD1
